Somatic mutation profile of tumor specimen TARGET-20-PARXNG-09A (aliquot TARGET-20-PARXNG-09A-02D) from TARGET case TARGET-20-PARXNG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.1 years (3,687 days).
Specimen TARGET-20-PARXNG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8040431a-9202-419e-9937-59d44e50a73f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARXNG-14A (Bone Marrow Normal), aliquot TARGET-20-PARXNG-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/290bc9cf-a295-4ca4-9b94-ceafe1ad811f

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 47/90 reads (52%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
- IKZF1 | c.409_412delinsGAGTGG p.R137Efs*57 | Frame Shift Ins (INS) | VAF 44/131 reads (34%) | called by pindel, varscan2*
- WT1 | c.1188dup p.Q397Tfs*10 | Frame Shift Ins (INS) | VAF 38/126 reads (30%) | called by mutect2, pindel, varscan2
